Somatic mutation profile of tumor specimen BA2314D (aliquot aq-BA2314D) from BEATAML1.0 case 2341, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Therapy related myeloid neoplasm; Tissue or organ of origin: Bone marrow; Age at diagnosis: 46.4 years (16,963 days).
Specimen BA2314D: Sample type: Recurrent Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Peripheral Blood NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0bebf513-b0bf-49f4-9932-4465ea9c840a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2141D (Solid Tissue Normal), aliquot aq-BA2141D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2003f701-9274-4237-954a-f08c5e7e0c53

The open-access MAF lists 36 somatic variants for this specimen: 19 protein-altering or splice-affecting, 10 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 17, Silent 10, RNA 4, 3'UTR 1, Splice Site 1, 5'UTR 1, 5'Flank 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CSMD3 | c.7940A>G p.D2647G (on ENST00000297405 / NM_001363185.1; = p.D2543G on NM_052900.3) | Missense Mutation (SNP) | VAF 20/176 reads (11%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.957); catalogued as rs561177908; called by muse, mutect2, varscan2
- DCAF15 | c.1457A>G p.N486S | Missense Mutation (SNP) | VAF 3/38 reads (8%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.994); catalogued as rs936844826; called by muse, mutect2
- FER1L6 | c.2330T>C p.V777A | Missense Mutation (SNP) | VAF 26/52 reads (50%) | SIFT deleterious (0.04); PolyPhen benign (0.282); catalogued as rs1266129283; called by muse, mutect2, varscan2
- FOXL2NB | c.238C>A p.Q80K | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.098); catalogued as COSV100374957; called by muse, mutect2
- OBSCN | c.12512C>T p.T4171M | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.459); catalogued as rs778801081, COSV52788497; called by muse, mutect2, varscan2
- POLQ | c.992A>G p.Y331C | Missense Mutation (SNP) | VAF 63/141 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs1288320990; called by muse, mutect2, varscan2
- SLC9A3 | c.772A>G p.S258G | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.262); catalogued as COSV53801619; called by muse, mutect2
- APOA5 | c.785C>A p.A262E | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.859); called by muse, mutect2
- AQP8 | c.22T>C p.C8R | Missense Mutation (SNP) | VAF 25/53 reads (47%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DOCK9 | c.1559A>G p.Y520C (on ENST00000376460 / NM_001366676.2; = p.Y521C on NM_015296.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.536); called by muse, mutect2, varscan2
- GRM5 | c.2341A>T p.T781S | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- HS3ST5 | c.802C>T p.L268F | Missense Mutation (SNP) | VAF 20/115 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.742); called by muse, mutect2, varscan2
- KDF1 | c.182T>C p.I61T | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- MYO15A | c.9341A>G p.Y3114C | Missense Mutation (SNP) | VAF 47/97 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, varscan2
- PTPRQ | c.1901C>G p.P634R (on ENST00000616559; = p.P592R on NM_001145026.2) | Missense Mutation (SNP) | VAF 11/165 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SDHD | c.169+2T>C p.X57_splice | Splice Site (SNP) | VAF 20/144 reads (14%) | called by mutect2, varscan2
- SLC25A42 | c.238A>G p.T80A | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.665); called by muse, mutect2, varscan2
- TNRC6B | c.1773_1776dup p.Y593Vfs*8 | Frame Shift Ins (INS) | VAF 12/100 reads (12%) | called by mutect2, varscan2
- ZNF429 | c.1694A>G p.Y565C | Missense Mutation (SNP) | VAF 24/158 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BLMH | c.840C>T p.Y280= | Silent (SNP) | VAF 27/94 reads (29%) | called by muse, mutect2, varscan2
- CCNH | c.498A>G p.P166= | Silent (SNP) | VAF 15/130 reads (12%) | catalogued as rs768003764; called by muse, mutect2
- DCLRE1A | c.3051T>C p.N1017= | Silent (SNP) | VAF 75/186 reads (40%) | called by muse, mutect2, varscan2
- DCP2 | c.69T>C p.H23= | Silent (SNP) | VAF 48/104 reads (46%) | catalogued as rs112366745; called by muse, mutect2, varscan2
- LAT2 | c.486G>A p.G162= | Silent (SNP) | VAF 3/50 reads (6%) | called by muse, mutect2
- OR5D16 | c.786T>C p.C262= | Silent (SNP) | VAF 25/96 reads (26%) | called by muse, mutect2, varscan2
- SUPV3L1 | c.768T>C p.G256= | Silent (SNP) | VAF 48/106 reads (45%) | called by muse, mutect2, varscan2
- TNFRSF1B | c.646T>C p.L216= | Silent (SNP) | VAF 18/74 reads (24%) | catalogued as rs1476651518; called by muse, mutect2, varscan2
- UHRF1BP1 | c.3375T>C p.S1125= | Silent (SNP) | VAF 12/42 reads (29%) | catalogued as COSV51961045; called by mutect2, varscan2
- ZBTB11 | c.603A>G p.L201= | Silent (SNP) | VAF 70/145 reads (48%) | called by muse, mutect2, varscan2
- C10orf88B | n.346A>G | RNA (SNP) | VAF 20/133 reads (15%) | called by muse, mutect2, varscan2
- CMTM5 | c.-18T>C | 5'UTR (SNP) | VAF 7/26 reads (27%) | called by muse, mutect2, varscan2
- LHCGR | c.*24T>A | 3'UTR (SNP) | VAF 13/68 reads (19%) | catalogued as COSV99683795; called by muse, mutect2, varscan2
- MSL3P1 | n.820A>G | RNA (SNP) | VAF 16/38 reads (42%) | called by mutect2, varscan2
- RRN3P1 | n.2622T>C | RNA (SNP) | VAF 8/251 reads (3%) | called by muse, mutect2
- TSPOAP1 | chr17:58331264 T>C | 5'Flank (SNP) | VAF 11/27 reads (41%) | called by muse, mutect2, varscan2
- WASH8P | n.1265A>G | RNA (SNP) | VAF 31/244 reads (13%) | catalogued as rs1555060736; called by muse, mutect2, varscan2
